Somatic mutation profile of tumor specimen TCGA-CE-A13K-01A (aliquot TCGA-CE-A13K-01A-11D-A10S-08) from TCGA case TCGA-CE-A13K, project TCGA-THCA (Thyroid Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Papillary adenocarcinoma, NOS; Tissue or organ of origin: Thyroid gland; AJCC pathologic stage: Stage I; Age at diagnosis: 30.5 years (11,122 days).
Specimen TCGA-CE-A13K-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 7ad7ef93-973e-48bc-8ce0-f819b276f224.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-CE-A13K-10A (Blood Derived Normal), aliquot TCGA-CE-A13K-10A-01D-A10S-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/7b8c7ccf-6edf-4d43-9308-1b72fbfdcd42

The open-access MAF lists 9 somatic variants for this specimen: 7 protein-altering or splice-affecting, 2 silent.
By variant classification: Missense Mutation 6, Silent 2, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- IFNL3 | c.443G>A p.R148Q | Missense Mutation (SNP) | VAF 16/126 reads (13%) | SIFT tolerated (0.5); PolyPhen benign (0.019); catalogued as rs146276429, COSV69829889; called by muse, mutect2, varscan2
- MDN1 | c.15296G>A p.R5099K | Missense Mutation (SNP) | VAF 8/78 reads (10%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.978); catalogued as COSV65520112; called by muse, mutect2, varscan2
- PAPSS1 | c.1355A>T p.H452L | Missense Mutation (SNP) | VAF 14/147 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.944); catalogued as COSV54488484; called by muse, mutect2
- PRRC2A | c.1547C>G p.S516C | Missense Mutation (SNP) | VAF 92/307 reads (30%) | SIFT deleterious (0.03); PolyPhen benign (0.054); catalogued as COSV63224447; called by muse, mutect2, varscan2
- SVIL | c.6086G>T p.S2029I (on ENST00000355867 / NM_021738.3; = p.S1603I on NM_003174.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 22/87 reads (25%) | SIFT deleterious (0.01); PolyPhen benign (0.083); catalogued as COSV63442196; called by muse, mutect2, varscan2
- TFPI2 | c.271+1G>T p.X91_splice | Splice Site (SNP) | VAF 24/58 reads (41%) | catalogued as rs1413016431, COSV55990384; called by muse, mutect2, varscan2
- TRAV36DV7 | c.242G>A p.R81K | Missense Mutation (SNP) | VAF 21/58 reads (36%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.721); called by muse, mutect2, varscan2
- PCDHGA3 | c.789G>A p.T263= | Silent (SNP) | VAF 37/95 reads (39%) | catalogued as rs752360843, COSV53927617; called by muse, mutect2, varscan2
- TRIML1 | c.1197C>T p.H399= | Silent (SNP) | VAF 88/206 reads (43%) | catalogued as rs768365819, COSV60193953, COSV60194759; called by muse, mutect2, varscan2
